Surgical pathology report (de-identified scan), TCGA case TCGA-ET-A2MX, project TCGA-THCA (Thyroid Carcinoma), tissue source site Johns Hopkins, specimen TCGA-ET-A2MX-01A (Primary Tumor).

[page 1 of 2]
IIIA Discrepancy		✓
hw 8/18/11		

SPECIMEN TAKEN:

FINAL DIAGNOSIS -----

1. THYROID (TOTAL THYROIDECTOMY):

SPECIMEN TYPE:

Total thyroidectomy

ICD-0-3

TUMOR SITE:

right lobe

carcinoma, papillary, thyroid 8260/3

HISTOLOGIC TYPE:

Papillary carcinoma

Site - thyroid, NOS C73.9

*hw
8/18/11*

TUMOR SIZE:

Greatest dimension: 2.1 cm

FOCALITY:

Unifocal

LYMPH NODES:

Metastatic carcinoma in 4 of 4 nodes (see part 2)

EXTENT OF INVASION

PRIMARY TUMOR:

pT2: Tumor >2cm but <4 cm, limited to thyroid

REGIONAL LYMPH NODES:

pN1a: Nodal metastasis to Level VI (pretracheal, paratracheal, and prelaryngeal/Delphian) nodes

DISTANT METASTASIS:

pMX: Cannot be assessed

MARGINS:

Margins are uninvolved

Distance of invasive carcinoma from nearest margin: 1 mm (anterior margin)

VENOUS/LYMPHATIC INVASION:

Present

[page 2 of 2]
NOTE: [REDACTED] has reviewed this case

2. CENTRAL LYMPH NODE AND THYMUS (DISSECTION):
METASTATIC PAPILLARY
THYROID CARCINOMA INVOLVING FOUR (4) OF FOUR (4) LYMPH
NODES.
HISTOLOGICALLY UNREMARKABLE THYMUS.

Source: NCI Genomic Data Commons file 04a6dc13-c10e-4091-8039-b8d51d84d6f4 (TCGA-ET-A2MX.302C0407-0160-499B-AD2C-496E8C3E2BDF.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).